Somatic mutation profile of tumor specimen TARGET-30-PAUDVA-09A (aliquot TARGET-30-PAUDVA-09A-01D) from TARGET case TARGET-30-PAUDVA, project TARGET-NBL (Neuroblastoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Neuroblastoma, NOS; Tissue or organ of origin: Adrenal gland, NOS; Age at diagnosis: 4.2 years (1,531 days).
Specimen TARGET-30-PAUDVA-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 21c9c450-7281-4f15-825e-8fa7e9a0ba6b.targeted_sequencing.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-30-PAUDVA-10A (Blood Derived Normal), aliquot TARGET-30-PAUDVA-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/2281cce0-ed5e-4847-8b93-d123d95513e6

The open-access MAF lists 1 somatic variant for this specimen: 1 silent.
By variant classification: Silent 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CELSR2 | c.7575C>A p.G2525= | Silent (SNP) | VAF 5/60 reads (8%) | called by muse, mutect2
